Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JZ, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JZ-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: M
ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: SPHS

Left adrenal mass. Operative Procedure/Tissue Submitted: Left adrenal mass excision.

PROCEDURE: SPGD

1. "Liver capsule, rule out metastatic adrenal cancer." A 0.5 cm, red-brown tissue fragment with a 0.1 cm white nodule. Frozen section control.
2. "Left adrenal gland with retroperitoneal fat, two short stitches equals superior, one long stitch equals lateral, two long stitch equals posterior". Received fresh for tissue procurement in a large container is a 585 gram (untrimmed weight), 17.2 x 12.5 x 5.4 cm mass with attached fat oriented as above. The mass itself measures 8.5 x 8.5 x 6.2 cm and grossly appears well encapsulated. Inked as per standard inking template. Untrimmed weight is 370 grams. Attached to the mass is a 5.5 x 1.0 cm adrenal gland. The cut surfaces show yellow soft focally hemorrhagic cut surfaces. The normal adrenal gland has an orange cortex and a brown medulla. The mass grossly appears to arise from the medulla. The attached fat has no gross abnormality.
- 2A and B. Tumor to adrenal gland to include anterior and medial margins.
- 2C. Tumor to include lateral margin.
- 2D. Tumor to include superior margin.
- 2E. Tumor with area of hemorrhage. No margins.
- 2F. Tumor to adjacent adrenal gland.
- 2G. Tumor to capsule.
- 2H. Additional representative section of tumor. No margin.
- 2I. Tumor to capsule.
- 2J. Representative sections of inferior and posterior margins from the attached fat.
3. "Left perirenal fat". Received in a medium container of formalin is a 7.5 x 4.4 x 0.4 cm piece of fibrofatty tissue with homogenous yellow cut surfaces. No lesions present. Representative sections in one cassette.

FROZEN SECTION REPORT

1. Fibrotic nodule with necrotic debris.

Permanent sections confirm frozen section report.

PROCEDURE: SPM1

ADRENOCORTICAL CARCINOMA

ICD-6-3
Carcinoma, adrenal cortical 8370/3
Site: Adrenal Gland, Cortex 874.0
Q10 1/30/13

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #:

2

BIRTHDATE:

PAT TYPE:

SEX: M

ADM DATE:

OPER DATE:

Tumor Size: 8.5 x 8.5 x 6.2 cm

Tumor Weight: 370 grams

Capsular Invasion: Present

Vascular Invasion: Absent

Surgical Margins: Negative

Necrosis: Present, focal (5%)

Mitotic Rate: 5/50 hpf

Grade: Low grade

Lymph nodes status: N/A

Extra-adrenal extension: No

Stage: T2 Nx Mx

Immunohistochemistry Results: See COMMENT.

PROCEDURE: SPDX

1. Liver capsule, biopsy: Negative for neoplasm.
2. Left adrenal gland, resection: Low grade adrenocortical carcinoma (8.5 cm), confined to the adrenal. Surgical margins negative. See TEMPLATE above and COMMENT below.
3. Left perirenal fat, excision: Benign fibroadipose tissue.

COMMENT

This carcinoma appears to be arising from a pre-existing adrenocortical adenoma, present on the periphery. The tumor cells show patchy positive staining for synaptophysin, melan-A, and inhibin; rare positive staining for cytokeratin, and negative staining for chromogranin and S-100. MIB-1 shows a proliferative index of approximately 20%. These results support a diagnosis of low grade adrenocortical carcinoma.

Prior Misdiagnosis History		

Source: NCI Genomic Data Commons file bc587279-18cf-40a4-ab7b-32ca5a489509 (TCGA-OR-A5JZ.90A9556D-C417-4FDB-AE1C-7ACB9F60E444.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).